Somatic mutation profile of tumor specimen TCGA-XK-AAJ3-01A (aliquot TCGA-XK-AAJ3-01A-11D-A41K-08) from TCGA case TCGA-XK-AAJ3, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 56.4 years (20,604 days).
Specimen TCGA-XK-AAJ3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f9de00a7-7111-4b50-92c5-25be3384e514.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XK-AAJ3-10A (Blood Derived Normal), aliquot TCGA-XK-AAJ3-10A-01D-A41N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e077ca40-ff31-46f9-9c52-3242cc1628a8

The open-access MAF lists 50 somatic variants for this specimen: 42 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 35, Silent 8, Frame Shift Del 3, Nonsense Mutation 2, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.904C>T p.R302* | Nonsense Mutation (SNP) | VAF 35/66 reads (53%) | catalogued as rs137854568, CM910029, COSV57324169; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 20/64 reads (31%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SPOP | c.393G>C p.W131C | Missense Mutation (SNP) | VAF 50/142 reads (35%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV61653780, COSV61655224; called by muse, mutect2, varscan2
- AGR3 | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 123/244 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.437); catalogued as rs1419894803, COSV100123922; called by muse, mutect2, varscan2
- ARHGAP20 | c.2164T>A p.Y722N | Missense Mutation (SNP) | VAF 51/123 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.841); catalogued as COSV99503635; called by muse, mutect2, varscan2
- ATG13 | c.326A>G p.K109R | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as COSV100365648; called by muse, mutect2, varscan2
- BBS7 | c.2050T>G p.F684V | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV99144872; called by muse, mutect2, varscan2
- BDKRB1 | c.900T>G p.F300L | Missense Mutation (SNP) | VAF 63/159 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99387807; called by muse, mutect2, varscan2
- BMPR1B | c.961A>C p.S321R | Missense Mutation (SNP) | VAF 40/90 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.32); catalogued as COSV99215638; called by muse, mutect2, varscan2
- BSN | c.8327C>T p.P2776L | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs369070758; called by muse, mutect2, varscan2
- CD1C | c.266G>A p.R89H | Missense Mutation (SNP) | VAF 38/103 reads (37%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as rs375747674; called by muse, mutect2, varscan2
- CDC73 | c.649G>C p.E217Q | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.563); catalogued as COSV100813792, COSV66471463; called by muse, mutect2, varscan2
- CNTNAP5 | c.3776C>T p.T1259I | Missense Mutation (SNP) | VAF 13/133 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs115436587, COSV101443326; called by muse, mutect2
- CROCC | c.785A>C p.N262T | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV100978145; called by muse, mutect2, varscan2
- CTCF | c.1577G>A p.S526N | Missense Mutation (SNP) | VAF 4/80 reads (5%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.75); catalogued as COSV99864941; called by muse, mutect2
- DLGAP4 | c.611G>C p.W204S | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100211070; called by muse, mutect2, varscan2
- DNAH10 | c.11128C>T p.R3710W (on ENST00000409039; = p.R3649W on NM_207437.3) | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200977125, COSV101292234; called by mutect2, varscan2
- GNAL | c.1076T>C p.I359T (on ENST00000269162 / NM_001142339.3; = p.I436T on NM_182978.4) | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1225290405, COSV99303311; called by muse, mutect2, varscan2
- GRAMD4 | c.1259G>A p.R420Q | Missense Mutation (SNP) | VAF 36/141 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.849); catalogued as rs1329075892, COSV63032612; called by muse, mutect2, varscan2
- GRIK3 | c.43T>C p.Y15H | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.146); catalogued as rs762028965, COSV100901762; called by muse, varscan2
- GRIP1 | c.2960T>C p.M987T (on ENST00000359742 / NM_001379345.1; = p.M935T on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 69/197 reads (35%) | SIFT tolerated (0.31); PolyPhen benign (0.03); catalogued as COSV99668961; called by muse, mutect2, varscan2
- HEATR9 | c.191G>T p.S64I | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.467); catalogued as rs1467289567; called by muse, mutect2, varscan2
- HECW2 | c.44G>A p.R15Q | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.978); catalogued as rs764980123, COSV53655313, COSV53671757; called by muse, mutect2, varscan2
- KCNK7 | c.889G>A p.A297T | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV100442114; called by muse, mutect2, varscan2
- LRRC8A | c.1772C>T p.A591V | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as rs760232174, COSV99396449; called by muse, mutect2, varscan2
- MYO3B | c.264T>A p.Y88* | Nonsense Mutation (SNP) | VAF 16/45 reads (36%) | catalogued as COSV100509841; called by muse, mutect2, varscan2
- NAF1 | c.778G>T p.D260Y | Missense Mutation (SNP) | VAF 62/163 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV99919028; called by muse, mutect2, varscan2
- NCF4 | c.117+2T>C p.X39_splice | Splice Site (SNP) | VAF 48/104 reads (46%) | catalogued as COSV99957238; called by muse, varscan2
- NPY5R | c.437C>G p.P146R | Missense Mutation (SNP) | VAF 78/210 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100642732; called by muse, mutect2, varscan2
- NUP98 | c.2611G>T p.G871C | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100262004; called by muse, mutect2, varscan2
- OR10K1 | c.800C>T p.T267I | Missense Mutation (SNP) | VAF 51/136 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV99193405; called by muse, mutect2, varscan2
- OR5A2 | c.566C>T p.S189F | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs760951443, COSV100119713; called by muse, mutect2, varscan2
- PCDH15 | c.812T>A p.V271E | Missense Mutation (SNP) | VAF 46/127 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100218579; called by muse, mutect2, varscan2
- POLR3D | c.1028A>G p.K343R | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs750545610, COSV100120038; called by muse, mutect2, varscan2
- RCVRN | c.599C>T p.A200V | Missense Mutation (SNP) | VAF 60/183 reads (33%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as rs1040016432, COSV99874142; called by muse, mutect2, varscan2
- UHRF2 | c.680A>G p.K227R | Missense Mutation (SNP) | VAF 40/105 reads (38%) | SIFT tolerated (0.46); PolyPhen benign (0.02); catalogued as COSV99436416; called by muse, mutect2, varscan2
- WSCD1 | c.37C>T p.R13C | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs893884983, COSV100496869, COSV58494722; called by muse, mutect2, varscan2
- ZAN | c.5546A>G p.E1849G | Missense Mutation (SNP) | VAF 38/73 reads (52%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.973); catalogued as COSV100769547; called by muse, mutect2, varscan2
- KDM6A | c.3160del p.R1054Efs*29 | Frame Shift Del (DEL) | VAF 52/96 reads (54%) | called by mutect2, pindel, varscan2
- MAP1B | c.7244_7245insTG p.M2416Afs*4 | Frame Shift Ins (INS) | VAF 11/35 reads (31%) | called by mutect2, pindel*, varscan2*
- UPF2 | c.940del p.H314Ifs*14 | Frame Shift Del (DEL) | VAF 29/101 reads (29%) | called by mutect2, pindel, varscan2
- ZFAT | c.3145del p.V1049Yfs*12 | Frame Shift Del (DEL) | VAF 10/36 reads (28%) | called by mutect2, pindel, varscan2
- ALDH1A1 | c.63T>A p.T21= | Silent (SNP) | VAF 25/65 reads (38%) | catalogued as COSV99921260; called by muse, mutect2, varscan2
- CEBPB | c.48G>A p.P16= | Silent (SNP) | VAF 8/16 reads (50%) | catalogued as rs778412840, COSV100269903; called by muse, varscan2
- DDX3Y | c.1677A>C p.V559= | Silent (SNP) | VAF 17/21 reads (81%) | catalogued as COSV100267514; called by muse, mutect2, varscan2
- DIDO1 | c.4560G>A p.L1520= | Silent (SNP) | VAF 30/87 reads (34%) | catalogued as COSV99825405; called by muse, mutect2, varscan2
- FZD4 | c.225C>G p.A75= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as COSV101536037; called by muse, varscan2
- PRKAG2 | c.870A>G p.K290= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as COSV99835108; called by muse, mutect2, varscan2
- RHBG | c.273C>T p.G91= | Silent (SNP) | VAF 66/184 reads (36%) | catalogued as COSV99659418; called by muse, mutect2, varscan2
- RUNX1T1 | c.1308T>A p.P436= (on ENST00000265814 / NM_001198628.1; = p.P409= on NM_004349.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 46/134 reads (34%) | catalogued as COSV99750999; called by muse, mutect2, varscan2
